Somatic mutation profile of tumor specimen TCGA-BK-A13B-01A (aliquot TCGA-BK-A13B-01A-51D-A228-09) from TCGA case TCGA-BK-A13B, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.8 years (21,493 days).
Specimen TCGA-BK-A13B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 744df358-d0f1-4d2c-b8f5-28052396ae61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A13B-10A (Blood Derived Normal), aliquot TCGA-BK-A13B-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/275f7881-f739-4f66-b95d-b68b5c1dd7dc

The open-access MAF lists 738 somatic variants for this specimen: 572 protein-altering or splice-affecting, 147 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 386, Silent 147, Frame Shift Del 96, Frame Shift Ins 36, Nonsense Mutation 28, Splice Site 14, In Frame Del 10, Intron 7, 3'UTR 4, RNA 4, 5'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.645+1G>A p.X215_splice | Splice Site (SNP) | VAF 25/50 reads (50%) | catalogued as rs863225370, CS072137, CS930756, COSV57341437; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CPT1A | c.281+1G>A p.X94_splice | Splice Site (SNP) | VAF 11/66 reads (17%) | catalogued as rs191107774, COSV99680656; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 20/47 reads (43%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- GCDH | c.1173del p.N392Mfs*9 | Frame Shift Del (DEL) | VAF 29/68 reads (43%) | catalogued as rs754002357; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- INSR | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as rs387906538, CM900142, COSV57163751; ClinVar: pathogenic; called by mutect2, varscan2
- KIF21A | c.2860C>T p.R954W (on ENST00000361418 / NM_001378440.1; = p.R941W on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs121912585, CM033625, COSV100735326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as rs72558417, CM1512785, CM950879, COSV50000745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1317_1319del p.E439del (on ENST00000521381 / NM_181523.3; = p.E169del on NM_181504.4) | In Frame Del (DEL) | VAF 16/30 reads (53%) | hotspot (GDC flag); catalogued as rs1131692242; called by pindel, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.47dup p.Y16* | Nonsense Mutation (INS) | VAF 18/53 reads (34%) | hotspot (GDC flag); catalogued as rs876661009, CI077458, COSV64293657; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 5/58 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1554900534, CM110153, COSV100909234, COSV64301647, COSV64303094; ClinVar: uncertain significance; called by muse, mutect2
- SOS1 | c.1654A>G p.R552G | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137852814, CM070269, CM122804, COSV101216611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.143); catalogued as COSV100741685; called by muse, mutect2, varscan2
- ABCC9 | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.353); catalogued as rs376754153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG5 | c.1808C>T p.T603I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV99570913; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs369735251; called by muse, mutect2, varscan2
- ACCS | c.418T>C p.F140L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV99772674; called by muse, mutect2, varscan2
- ACOT8 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99467377; called by muse, mutect2, varscan2
- ACSL1 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as COSV99860380; called by muse, mutect2, varscan2
- ACTR10 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV54300230; called by muse, mutect2
- ADAM11 | c.104del p.G35Afs*52 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs767694891; called by mutect2, pindel, varscan2
- ADAMTSL4 | c.963del p.T322Lfs*21 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs748115277, COSV55000781; called by mutect2, pindel, varscan2
- ADCY5 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV101518392; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.518T>G p.V173G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV100416237; called by muse, mutect2, varscan2
- ADGRA3 | c.3789del p.D1264Mfs*3 | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | catalogued as rs778863401; called by mutect2, pindel, varscan2
- ADGRF5 | c.3292C>A p.L1098I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99345007; called by muse, mutect2, varscan2
- AFG3L2 | c.1664-1G>T p.X555_splice | Splice Site (SNP) | VAF 8/11 reads (73%) | catalogued as COSV99301552; called by muse, mutect2, varscan2
- AHCY | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs775953872, COSV54152552; called by muse, mutect2, varscan2
- AKAP6 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55216527; called by muse, mutect2, varscan2
- AKAP6 | c.5687del p.N1896Mfs*17 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as COSV99800479; called by mutect2, pindel, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKR1E2 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs528543697, COSV100033391; called by muse, mutect2, varscan2
- AL592490.1 | c.2820G>A p.M940I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV101308115; called by muse, mutect2, varscan2
- AL592490.1 | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV101308116; called by muse, mutect2, varscan2
- ALKBH1 | c.1087A>G p.R363G | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV99380450; called by muse, mutect2, varscan2
- AMIGO3 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs549227386, COSV100246449, COSV57538017; called by muse, mutect2, varscan2
- AMZ1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs201858896, COSV100406206; called by muse, mutect2, varscan2
- ANKLE2 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV100513952; called by muse, mutect2, varscan2
- ANO6 | c.1522A>G p.T508A | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV100262445; called by muse, mutect2, varscan2
- AOC1 | c.2165G>A p.G722D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV100710626; called by muse, mutect2
- APC2 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs371129014, COSV52021013; called by muse, mutect2, varscan2
- APOB | c.9830C>T p.A3277V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs907962079, COSV99263888; called by muse, mutect2, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 54/124 reads (44%) | catalogued as rs3215969; called by mutect2, varscan2
- ARHGAP28 | c.1456G>T p.G486W (on ENST00000383472 / NM_001366230.1; = p.G327W on NM_001010000.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.623); catalogued as COSV99148703; called by muse, mutect2
- ARHGEF6 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV99166360; called by muse, mutect2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARX | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as COSV100984040; called by mutect2, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 10/18 reads (56%) | catalogued as rs747570359; called by mutect2, varscan2
- ASMTL | c.1490del p.G497Dfs*74 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs1569532359; called by mutect2, pindel, varscan2
- ATAD2B | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV99477060; called by muse, mutect2, varscan2
- ATF3 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs756952643, COSV58378340; called by muse, mutect2, varscan2
- ATG10 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99966604; called by muse, mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATP8A1 | c.2845C>A p.L949I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as COSV100045146; called by muse, mutect2, varscan2
- ATP8A1 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV100045150; called by muse, mutect2, varscan2
- BAIAP3 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99136139; called by muse, mutect2, varscan2
- BBS12 | c.1514C>T p.T505I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100044816; called by muse, mutect2, varscan2
- BCAS2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as rs1332220520, COSV101058548; called by muse, mutect2, varscan2
- BCL7C | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.407); catalogued as COSV99288499; called by muse, mutect2, varscan2
- BCOR | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1231642126, COSV60702643; called by muse, mutect2, varscan2
- BRD3 | c.443T>C p.L148S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.611); catalogued as COSV100324719; called by muse, mutect2, varscan2
- BRF1 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100526882; called by muse, mutect2, varscan2
- BTG4 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100604354; called by muse, mutect2, varscan2
- BTNL3 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100732180; called by muse, mutect2, varscan2
- C1D | c.359dup p.N120Kfs*17 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | catalogued as rs776000138; called by mutect2, pindel, varscan2
- C1QL2 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs895486904, COSV99733071; called by muse, mutect2
- C1QTNF3 | c.167del p.P56Lfs*96 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs761303952; called by mutect2, pindel, varscan2
- C3 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs1447175740, COSV99836132; called by muse, mutect2, varscan2
- C5orf24 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV100574447; called by muse, mutect2, varscan2
- C9orf131 | c.1524G>T p.W508C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.415); catalogued as COSV100397944; called by muse, mutect2, varscan2
- CACNA1E | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs377231001; called by muse, mutect2, varscan2
- CACNA2D3 | c.2528G>A p.G843D | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs867611273, COSV99870815; called by muse, mutect2, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs201838505; called by mutect2, varscan2
- CAPN15 | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs201622777, COSV54835403; called by muse, mutect2, varscan2
- CAPRIN2 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99195424; called by muse, mutect2, varscan2
- CAPZB | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1311754922, COSV51647898; called by muse, mutect2, varscan2
- CARF | c.897del p.V300Sfs*55 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs751635415; called by mutect2, pindel, varscan2
- CCDC130 | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.091); catalogued as COSV99237250; called by muse, mutect2
- CCDC153 | c.599dup p.G201Wfs*9 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs745729530; called by mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 51/112 reads (46%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC18 | c.965T>C p.M322T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100159266; called by muse, mutect2
- CCDC18 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100159269; called by muse, mutect2, varscan2
- CCDC27 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as rs750795328, COSV99622155; called by muse, mutect2, varscan2
- CCDC88C | c.6067T>A p.Y2023N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100484673; called by muse, mutect2, varscan2
- CCDC92 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1404252578, COSV99435251; called by muse, mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs761073142; called by mutect2, varscan2
- CD1B | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV100939147; called by muse, mutect2, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as rs1276928429, COSV55666935; called by mutect2, pindel, varscan2
- CDC27 | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs75580209, COSV99294034; called by muse, mutect2, varscan2
- CDC45 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201658114; called by muse, mutect2, varscan2
- CDCP1 | c.1331A>G p.H444R | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99943866; called by muse, mutect2, varscan2
- CDH16 | c.1539A>T p.R513S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.197); catalogued as COSV100233678; called by muse, mutect2, varscan2
- CDH22 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1004210893, COSV64839960; called by muse, mutect2, varscan2
- CDH3 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV99867665; called by muse, mutect2, varscan2
- CDK6 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99720782; called by muse, mutect2, varscan2
- CELSR3 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV99372697; called by mutect2, varscan2
- CETP | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs748488549, CM983856, COSV99569878; called by muse, mutect2, varscan2
- CHD3 | c.2983T>C p.Y995H | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100390782; called by muse, mutect2, varscan2
- CHMP6 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV100289407; called by mutect2, varscan2
- CHRNB1 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs752778673, COSV100043451; called by muse, mutect2, varscan2
- CHST1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as COSV57323520; called by muse, mutect2
- CHST7 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.225); catalogued as COSV99332788; called by muse, mutect2, varscan2
- CLK2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs757792688, COSV62876539; called by muse, mutect2, varscan2
- CNOT6L | c.917C>T p.A306V (on ENST00000504123 / NM_001286790.2; = p.A301V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1481358623, COSV53698148; called by muse, mutect2, varscan2
- CNTN2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs573652423, COSV59351367; called by muse, mutect2, varscan2
- CNTNAP4 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1479349316, COSV56686972, COSV56693705; called by muse, mutect2, varscan2
- COL20A1 | c.3212C>A p.P1071H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100489992; called by muse, mutect2, varscan2
- COL7A1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs866241910, COSV52550850; called by muse, mutect2, varscan2
- COL9A2 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101028390; called by muse, mutect2, varscan2
- COP1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as COSV58175646; called by muse, mutect2, varscan2
- COX6A1 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377211866; called by muse, mutect2, varscan2
- CRACR2B | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs973116910, COSV100431698; called by muse, mutect2, varscan2
- CSE1L | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV99521862; called by muse, mutect2, varscan2
- CSMD3 | c.5448G>T p.E1816D (on ENST00000297405 / NM_001363185.1; = p.E1712D on NM_052900.3) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV99822278; called by muse, mutect2, varscan2
- CSNK2A2 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1465113121, COSV99345172; called by muse, mutect2, varscan2
- CTSW | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1356807190, COSV100327218; called by muse, mutect2
- CYB561D1 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs765878493, COSV100149754; called by muse, mutect2, varscan2
- DDR2 | c.533T>C p.M178T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100906219; called by muse, mutect2, varscan2
- DDX25 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764678102, COSV99699685; called by muse, mutect2, varscan2
- DENND1A | c.2818C>G p.L940V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.13); catalogued as COSV101011822; called by muse, mutect2, varscan2
- DENND1A | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101011824; called by muse, mutect2, varscan2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs35538077; called by mutect2, pindel, varscan2
- DHX32 | c.1058G>T p.R353I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1433624184, COSV99501410; called by muse, mutect2, varscan2
- DHX32 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99501412; called by muse, mutect2, varscan2
- DHX34 | c.208T>A p.F70I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV100169291; called by muse, mutect2, varscan2
- DHX37 | c.1673A>C p.E558A | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV100439010; called by muse, mutect2, varscan2
- DMXL1 | c.1569G>T p.Q523H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV100223396; called by muse, mutect2, varscan2
- DMXL1 | c.4822G>A p.V1608M | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV100223398; called by muse, mutect2, varscan2
- DNA2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as COSV100622391, COSV64428811; called by muse, mutect2, varscan2
- DNAH3 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as rs775586516, COSV54519462; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAJC7 | c.1372A>G p.M458V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs781879792, COSV100347533; called by muse, mutect2, varscan2
- DNASE1L3 | c.822C>A p.H274Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100568596; called by muse, mutect2, varscan2
- DNMT3A | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs755631209, COSV99259823; called by muse, mutect2, varscan2
- DOCK6 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779753968, COSV99624893; called by muse, mutect2, varscan2
- DSCAM | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs760068335, COSV68026595; called by muse, mutect2, varscan2
- DXO | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.307); catalogued as rs12205138, COSV100514568; called by muse, mutect2, varscan2
- DYNC2I1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as rs376591105; called by muse, mutect2, varscan2
- EEPD1 | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99631815; called by muse, mutect2, varscan2
- EFNA3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV100860782, COSV100860798; called by muse, mutect2, varscan2
- EGR1 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99525305; called by muse, mutect2, varscan2
- ELANE | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM078496, COSV99708672, COSV99708695; called by muse, mutect2, varscan2
- ELAVL1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60967120; called by muse, mutect2
- ELFN2 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.137); catalogued as COSV101297481; called by muse, mutect2, varscan2
- ELK4 | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV99222251; called by muse, mutect2, varscan2
- ELP1 | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as COSV101010350; called by muse, mutect2, varscan2
- ENO3 | c.1099del p.V367* | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs961001512; called by mutect2, pindel, varscan2
- EPHA4 | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV99915729; called by muse, mutect2, varscan2
- EPHA4 | c.568del p.A190Pfs*144 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as COSV99916698; called by mutect2, pindel, varscan2
- EPS8L1 | c.1086dup p.P363Afs*28 (on ENST00000201647 / NM_133180.3; = p.P236Afs*28 on NM_017729.3) | Frame Shift Ins (INS) | VAF 14/84 reads (17%) | catalogued as rs746955003; called by mutect2, varscan2
- EPS8L1 | c.1301G>A p.R434H (on ENST00000201647 / NM_133180.3; = p.R307H on NM_017729.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV52382610; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 30/63 reads (48%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOSC9 | c.282-1G>T p.X94_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99696772; called by muse, mutect2, varscan2
- EXT2 | c.68G>A p.R23Q (on ENST00000343631; = p.R56Q on NM_000401.3) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as rs369368661; called by muse, mutect2, varscan2
- FANCB | c.750C>A p.N250K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV100146403; called by muse, mutect2, varscan2
- FANCD2 | c.4333A>T p.I1445F | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV99810494; called by muse, mutect2, varscan2
- FASTKD1 | c.78G>C p.W26C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV101328478; called by muse, mutect2, varscan2
- FASTKD5 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV99417472; called by muse, mutect2, varscan2
- FBXL6 | c.994-3del | Splice Region (DEL) | VAF 38/92 reads (41%) | catalogued as rs1564648530; called by mutect2, pindel, varscan2
- FBXO15 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200318148, COSV54049826; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs748969702; called by mutect2, varscan2
- FGF13 | c.68dup p.G24Wfs*28 | Frame Shift Ins (INS) | VAF 12/24 reads (50%) | catalogued as rs766041577; called by mutect2, varscan2
- FHOD1 | c.1115dup p.C373Lfs*59 | Frame Shift Ins (INS) | VAF 7/25 reads (28%) | catalogued as rs1285749985; called by mutect2, pindel
- FLG | c.8344G>A p.G2782S | Missense Mutation (SNP) | VAF 101/393 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs748391293, COSV64246443; called by muse, mutect2, varscan2
- FLG | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs779906299, COSV100910628; called by muse, mutect2, varscan2
- FLT3LG | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV99201278; called by muse, mutect2, varscan2
- FLVCR1 | c.1283T>C p.V428A | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV100875000; called by muse, mutect2
- FMN1 | c.3494C>T p.T1165M (on ENST00000616417 / NM_001277313.2; = p.T942M on NM_001103184.4) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs201413508; called by mutect2, varscan2
- FMO1 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV100707701; called by muse, mutect2, varscan2
- FMO2 | c.322-1G>A p.X108_splice | Splice Site (SNP) | VAF 25/122 reads (20%) | catalogued as COSV99268923; called by muse, mutect2, varscan2
- FNDC1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762962324, COSV51951173; called by muse, mutect2, varscan2
- FNDC1 | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1417434518, COSV51947634; called by muse, mutect2, varscan2
- FOCAD | c.4450G>T p.G1484C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as COSV100620094; called by muse, mutect2, varscan2
- FOXO4 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV100446787; called by muse, mutect2, varscan2
- FRYL | c.2914C>T p.R972W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51944306; called by muse, mutect2, varscan2
- FTSJ3 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as COSV100037195; called by muse, mutect2
- GAB2 | c.562G>A p.A188T (on ENST00000361507 / NM_080491.3; = p.A150T on NM_012296.3) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); catalogued as rs1459019032, COSV100416273; called by muse, mutect2, varscan2
- GABRQ | c.1754G>T p.S585I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV100941105; called by muse, mutect2, varscan2
- GLP2R | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52330272; called by muse, mutect2, varscan2
- GNPTAB | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs775948211, COSV54777029; called by muse, mutect2, varscan2
- GPR135 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs540383538, COSV101229296; called by muse, mutect2, varscan2
- GPR179 | c.1529C>T p.T510I (on ENST00000621958; = p.T509I on NM_001004334.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043449927; called by muse, mutect2, varscan2
- GPR19 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100196783; called by muse, mutect2, varscan2
- GPR50 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV99505727; called by muse, mutect2, varscan2
- GPT2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs1205102812, COSV60840409; called by muse, mutect2, varscan2
- GRAMD1C | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as rs374737363; called by muse, mutect2, varscan2
- GRID1 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.202); catalogued as COSV100022199; called by muse, mutect2, varscan2
- GSDMC | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as COSV99415627; called by muse, mutect2
- GTDC1 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.76); catalogued as COSV99599570; called by muse, mutect2
- H3C11 | c.97del p.T33Pfs*30 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | catalogued as COSV58899862; called by mutect2, pindel, varscan2
- HEATR1 | c.5009C>T p.A1670V | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201522356, COSV63983326; called by muse, mutect2, varscan2
- HIVEP1 | c.5944A>G p.T1982A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201234299; called by muse, mutect2, varscan2
- HLA-DOA | c.467A>C p.E156A | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV100008108; called by muse, mutect2, varscan2
- HMCN1 | c.8785C>T p.Q2929* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99624777; called by muse, mutect2, varscan2
- HPN | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1291103607, COSV52882068; called by muse, mutect2, varscan2
- HR | c.1052del p.G351Vfs*12 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs750438737; called by mutect2, pindel, varscan2
- HSD17B11 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as rs777162512, COSV64154324; called by muse, mutect2, varscan2
- HSPA12B | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99653863; called by muse, mutect2, varscan2
- HYOU1 | c.2516C>G p.A839G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs372174234; called by muse, mutect2
- ICAM5 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99703151; called by muse, mutect2, varscan2
- ICE1 | c.4845T>A p.D1615E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99663886; called by muse, mutect2, varscan2
- IFI30 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99717230; called by muse, mutect2, varscan2
- IGSF10 | c.4656G>A p.M1552I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV99176780; called by muse, mutect2, varscan2
- IK | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as rs1246484640, COSV70258219; called by muse, mutect2, varscan2
- INPP5F | c.2333T>C p.M778T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs202058130, COSV100739997; called by muse, mutect2, varscan2
- INPPL1 | c.2160del p.V721Cfs*37 | Frame Shift Del (DEL) | VAF 25/75 reads (33%) | catalogued as COSV53359298; called by mutect2, pindel, varscan2
- IQGAP2 | c.4241G>A p.R1414Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1383698178, COSV57168674; called by muse, mutect2, varscan2
- IRS1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100524082; called by muse, mutect2, varscan2
- ISM1 | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99339624; called by muse, mutect2, varscan2
- ITGA4 | c.571T>A p.F191I | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs775360380, COSV51999469; called by muse, mutect2, varscan2
- JAK3 | c.3232T>C p.W1078R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101512886; called by muse, mutect2, varscan2
- JAK3 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs768522857, COSV101512887; called by muse, mutect2, varscan2
- JCAD | c.4045G>T p.D1349Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100948123; called by muse, mutect2, varscan2
- JPH3 | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as COSV99412893; called by muse, mutect2, varscan2
- JPH4 | c.1491G>T p.E497D | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.424); catalogued as COSV100436581; called by muse, mutect2, varscan2
- KAT2B | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as rs771888629, COSV99768949; called by muse, mutect2, varscan2
- KAT6A | c.5434C>T p.P1812S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV99704483; called by muse, mutect2, varscan2
- KDM6B | c.4522G>A p.V1508I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV99640802; called by muse, mutect2, varscan2
- KIDINS220 | c.3167C>T p.P1056L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99875072; called by muse, mutect2, varscan2
- KIF13B | c.5131G>A p.A1711T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757880042, COSV101342247; called by muse, mutect2, varscan2
- KIR3DL2 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99551799; called by muse, mutect2, varscan2
- KLK4 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100133540; called by muse, mutect2, varscan2
- KLRC4 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV100511253; called by muse, mutect2, varscan2
- KMT2B | c.7451G>A p.R2484H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1285582819, COSV99718944; called by muse, mutect2, varscan2
- KPNA3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99903929; called by muse, mutect2, varscan2
- KRT2 | c.1900G>A p.V634M | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs150413930; called by muse, mutect2, varscan2
- KSR1 | c.872dup p.P292Tfs*22 (on ENST00000644974 / NM_001367810.1; = p.P155Tfs*22 on NM_014238.2) | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA5 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs1401931687, COSV99438315; called by muse, mutect2, varscan2
- LAMB2 | c.4616G>A p.R1539Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.734); catalogued as rs758539618, COSV100025875; called by muse, varscan2
- LARP4B | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV60220193; called by muse, mutect2, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs746633076; called by mutect2, varscan2
- LATS2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as rs1466832911, COSV101231482; called by muse, mutect2, varscan2
- LCP2 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs770608317, COSV50448581; called by muse, mutect2, varscan2
- LCT | c.5087C>T p.A1696V | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV51544410, COSV51554963; called by muse, mutect2, varscan2
- LHX3 | c.248del p.F83Sfs*90 (on ENST00000371748 / NM_178138.6; = p.F88Sfs*90 on NM_014564.5) | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs1564284082; called by mutect2, pindel, varscan2
- LIPN | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV101356210; called by muse, mutect2, varscan2
- LLGL1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.11); catalogued as COSV100375090; called by muse, mutect2, varscan2
- LLPH | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 37/326 reads (11%) | catalogued as COSV99874463; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 12/29 reads (41%) | catalogued as rs765287063; called by mutect2, varscan2
- LPAR5 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as rs754597466, COSV100320934; called by muse, mutect2, varscan2
- LRFN4 | c.1571del p.G524Vfs*100 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as COSV100540885; called by mutect2, varscan2
- LRRN2 | c.95A>G p.Q32R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100912758; called by muse, mutect2, varscan2
- LRRTM4 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as rs1421250034, COSV69183154; called by muse, mutect2, varscan2
- LSS | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1385271707, COSV100710813; called by muse, mutect2, varscan2
- LZIC | c.443A>C p.D148A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101021283; called by muse, mutect2, varscan2
- LZTS3 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV100232153; called by muse, mutect2, varscan2
- MACF1 | c.12787-1G>T p.X4263_splice (on ENST00000372915; = p.X2196_splice on NM_012090.5) | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV57112970, COSV99241677; called by muse, mutect2
- MAML3 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs1486656582, COSV101558351; called by muse, mutect2, varscan2
- MAP10 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV101406439; called by muse, mutect2
- MAP2K1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1473690179, COSV61070930; called by muse, mutect2, varscan2
- MAX | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs776978293, COSV52416114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCF2L2 | c.956G>A p.C319Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV100191461; called by muse, mutect2, varscan2
- MCTS1 | c.95A>G p.Q32R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100989134; called by muse, mutect2, varscan2
- MEGF10 | c.2897A>G p.N966S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99174738; called by muse, mutect2, varscan2
- METTL2A | c.915dup p.G306Rfs*13 | Frame Shift Ins (INS) | VAF 23/64 reads (36%) | catalogued as rs894864347; called by mutect2, pindel, varscan2
- METTL8 | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as rs1443117275, COSV100930963; called by muse, mutect2, varscan2
- MGAT5B | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100047370; called by muse, mutect2, varscan2
- MKI67 | c.5569del p.I1857Yfs*30 | Frame Shift Del (DEL) | VAF 50/112 reads (45%) | catalogued as rs866533107; called by mutect2, varscan2
- MKI67 | c.3385T>C p.C1129R | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV100896208; called by muse, mutect2
- MMP15 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356216183, COSV54678756; called by muse, mutect2, varscan2
- MMP9 | c.1290dup p.H432Afs*2 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | catalogued as rs768099775; called by mutect2, pindel, varscan2
- MRPL58 | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751797695, COSV100042964, COSV56901046; called by muse, mutect2, varscan2
- MRPS25 | c.89T>C p.M30T | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs1039643335, COSV99507661; called by muse, mutect2, varscan2
- MS4A10 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.339); catalogued as COSV100382216, COSV57633734; called by muse, mutect2, varscan2
- MSL2 | c.178T>A p.S60T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.351); catalogued as COSV99386538; called by muse, mutect2, varscan2
- MTCL1 | c.2311C>T p.P771S (on ENST00000306329 / NM_001378206.1; = p.P411S on NM_015210.4) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1348467795, COSV60409282; called by muse, mutect2
- MTMR7 | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as rs776791101, COSV99472000; called by muse, mutect2, varscan2
- MTSS2 | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV99851740; called by muse, mutect2, varscan2
- MUC16 | c.40378G>A p.A13460T | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (0.983); catalogued as rs1259444117, COSV101109654; called by muse, mutect2, varscan2
- MXRA5 | c.6867G>A p.M2289I | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV99475962; called by muse, mutect2, varscan2
- MYCBP2 | c.3545A>G p.Q1182R (on ENST00000357337; = p.Q1220R on NM_015057.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV100629330; called by muse, mutect2, varscan2
- MYH14 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768787467, COSV99221754; called by muse, mutect2, varscan2
- MYH3 | c.3102+1G>A p.X1034_splice | Splice Site (SNP) | VAF 8/90 reads (9%) | catalogued as rs756111159, COSV56868281; called by muse, mutect2
- MYH7B | c.5583G>T p.Q1861H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV99327867; called by muse, mutect2, varscan2
- MYLIP | c.1207G>T p.G403C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100785914; called by muse, mutect2
- MYOG | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99613843; called by muse, mutect2, varscan2
- MYT1L | c.2164C>T p.H722Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV101219102; called by muse, mutect2, varscan2
- NAGS | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1345674210, COSV99243707; called by muse, mutect2
- NAV2 | c.1102T>C p.S368P (on ENST00000396087 / NM_001244963.2; = p.S345P on NM_145117.5) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV100584943; called by muse, mutect2, varscan2
- NCOR2 | c.2956dup p.R986Pfs*76 | Frame Shift Ins (INS) | VAF 18/40 reads (45%) | catalogued as rs746871841; called by mutect2, varscan2
- NEB | c.6235C>T p.R2079C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753064438, COSV51119278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101455625; called by muse, mutect2, varscan2
- NHLRC2 | c.1096A>G p.I366V | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV100992895; called by muse, mutect2, varscan2
- NLRP4 | c.2650T>A p.L884M | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015707, COSV56712632; called by muse, mutect2
- NOTCH1 | c.7291C>T p.R2431W | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs758410389, COSV99485752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH2 | c.6631G>A p.A2211T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1352940498, COSV99862961; called by muse, mutect2, varscan2
- NOTUM | c.1436A>G p.Q479R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV101293753; called by muse, mutect2, varscan2
- NPEPPS | c.1654C>A p.P552T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV100443447; called by muse, mutect2, varscan2
- NPR2 | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as rs995457759, COSV100709321, COSV100709431; called by muse, mutect2, varscan2
- NRP2 | c.1651G>T p.G551W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99783593; called by muse, mutect2, varscan2
- NRXN2 | c.4280C>T p.T1427M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV99632676; called by muse, mutect2, varscan2
- NSD1 | c.4709G>A p.C1570Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM052303, COSV100728509; called by muse, mutect2, varscan2
- NT5C1B | c.506C>T p.P169L (on ENST00000359846 / NM_001199086.2; = p.P109L on NM_033253.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1399070348, COSV100409803; called by muse, mutect2, varscan2
- NTN4 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as rs1314102993, COSV59217497, COSV59223961; called by muse, mutect2, varscan2
- OLFM1 | c.857C>T p.T286M (on ENST00000371793 / NM_001282611.2; = p.T268M on NM_014279.5) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs372599021; called by muse, mutect2, varscan2
- OLFML2A | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778041459, COSV56582890; called by muse, mutect2, varscan2
- OR2G2 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); catalogued as rs370574982, COSV60739683; called by muse, mutect2, varscan2
- OR2T12 | c.431T>C p.M144T | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV100527564; called by muse, mutect2, varscan2
- OR2W3 | c.868T>G p.Y290D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200234751, COSV100831606; called by muse, mutect2, varscan2
- OR5K2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV71143558; called by muse, mutect2
- OR8G5 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.031); catalogued as COSV100422262, COSV100422549, COSV58380413; called by muse, mutect2
- OXR1 | c.2320-2A>G p.X774_splice (on ENST00000442977 / NM_001198532.1; = p.X746_splice on NM_018002.3) | Splice Site (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99860804; called by muse, mutect2, varscan2
- P3H3 | c.2021C>T p.T674M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782219273, COSV51834932; called by muse, mutect2, varscan2
- PCDH10 | c.631G>T p.G211* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV52092166, COSV99993070; called by muse, varscan2
- PCDH9 | c.2809A>G p.K937E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV100118692; called by muse, mutect2, varscan2
- PCDHA5 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as COSV100972133; called by muse, mutect2, varscan2
- PCDHAC2 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.533); catalogued as COSV99144517; called by muse, mutect2, varscan2
- PCDHB16 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1554282239, COSV53365382; called by muse, mutect2
- PCDHB6 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV99169938; called by muse, mutect2, varscan2
- PCDHGA8 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as rs760367783, COSV53901869; called by muse, mutect2, varscan2
- PCMTD2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.66); PolyPhen benign (0.115); catalogued as rs1267441727, COSV55062064, COSV99829502; called by muse, mutect2, varscan2
- PCNX4 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100469963; called by muse, mutect2, varscan2
- PCSK6 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs757548126, COSV100082966, COSV100083110; called by muse, mutect2, varscan2
- PDE6B | c.622-2A>G p.X208_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | catalogued as rs1474155893, COSV99726954; called by muse, mutect2, varscan2
- PDE9A | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99371114; called by muse, mutect2, varscan2
- PDHA2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.785); catalogued as COSV54777059; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs759495724; called by mutect2, varscan2
- PGLYRP3 | c.974C>A p.P325H | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319506; called by muse, mutect2, varscan2
- PHF6 | c.499C>T p.P167S (on ENST00000332070 / NM_032458.3; = p.P168S on NM_032335.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100136269; called by muse, mutect2, varscan2
- PIK3C3 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.093); catalogued as COSV100010445; called by muse, mutect2, varscan2
- PITX2 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as COSV61585033; called by muse, mutect2, varscan2
- PLA2G7 | c.799del p.I267* | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs377632936; called by mutect2, pindel, varscan2
- PLA2R1 | c.4093C>T p.Q1365* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV51783715; called by muse, mutect2, varscan2
- PLD1 | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100577698; called by muse, mutect2
- PLEKHH3 | c.2066C>A p.A689D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99257334; called by muse, mutect2, varscan2
- PODXL | c.910G>A p.A304T (on ENST00000378555 / NM_001018111.3; = p.A272T on NM_005397.4) | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.135); catalogued as rs759031194, COSV100539263; called by muse, mutect2, varscan2
- POU5F2 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as COSV67940653; called by muse, mutect2
- PPARA | c.1399A>G p.M467V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV99415198; called by muse, mutect2, varscan2
- PPFIA1 | c.1708-1G>T p.X570_splice | Splice Site (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99556919; called by muse, mutect2
- PRAMEF15 | c.734A>G p.D245G | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as rs1299480371; called by muse, mutect2, varscan2
- PRDM9 | c.1771T>C p.W591R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs200381384; called by muse, varscan2
- PRPF4 | c.1463C>G p.A488G (on ENST00000374198 / NM_001322267.2; = p.A489G on NM_004697.5) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.559); catalogued as COSV100950633; called by muse, mutect2, varscan2
- PRR14 | c.1594C>T p.R532* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as rs968269730, COSV54912325; called by muse, mutect2, varscan2
- PRRC2C | c.8048C>T p.T2683I (on ENST00000367742; = p.T2681I on NM_015172.4) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV58904369; called by muse, mutect2, varscan2
- PTEN | c.106G>C p.G36R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs786204854, CM004280, CM124222, COSV100909550, COSV64289957, COSV64297290; called by muse, mutect2, varscan2
- PTPN23 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.159); catalogued as COSV99650238; called by muse, mutect2, varscan2
- PTPRG | c.2165del p.N722Tfs*5 | Frame Shift Del (DEL) | VAF 39/98 reads (40%) | catalogued as rs869306841; called by mutect2, pindel, varscan2
- PTPRG | c.3719A>G p.D1240G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99873232; called by muse, mutect2, varscan2
- PTPRK | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.597); catalogued as COSV100950462; called by muse, mutect2, varscan2
- PUM3 | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs757550173, COSV101193140; called by muse, varscan2
- PVRIG | c.236dup p.N81Qfs*61 | Frame Shift Ins (INS) | VAF 14/99 reads (14%) | catalogued as rs768997455; called by mutect2, varscan2
- PYCR2 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100661481; called by muse, mutect2, varscan2
- RAB11FIP4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs528803225, COSV100365159; called by muse, mutect2, varscan2
- RAB23 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.263); catalogued as rs150655349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RABEP1 | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs760132791, COSV52584161; called by muse, mutect2, varscan2
- RABGGTA | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs373544140; called by muse, mutect2, varscan2
- RANBP3 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.241); catalogued as COSV99222166; called by muse, mutect2, varscan2
- RAPGEF5 | c.1615A>C p.T539P (on ENST00000401957 / NM_001367602.2; = p.T842P on NM_012294.5) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100686553; called by muse, mutect2, varscan2
- RBM25 | c.2117T>C p.V706A | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as COSV56202835; called by muse, mutect2
- RBM33 | c.3089dup p.L1031Pfs*109 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | catalogued as rs766836538; called by mutect2, varscan2
- RBM8A | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV100355212; called by muse, mutect2, varscan2
- REV3L | c.5585C>A p.P1862H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV100724923; called by muse, mutect2
- RGL1 | c.1058A>G p.D353G (on ENST00000360851 / NM_001297672.2; = p.D388G on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100486252; called by muse, mutect2
- RGS14 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs755466098, COSV101281697; called by muse, mutect2, varscan2
- RHBDL3 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV99283557; called by muse, mutect2, varscan2
- RIC8A | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100254726; called by muse, mutect2, varscan2
- RIMBP2 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV99898519; called by muse, mutect2, varscan2
- RINL | c.1607C>T p.T536M (on ENST00000591812 / NM_001195833.2; = p.T422M on NM_198445.4) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100531002; called by muse, mutect2, varscan2
- RNF152 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100455019; called by muse, mutect2, varscan2
- ROBO1 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as COSV101458334; called by muse, mutect2, varscan2
- RORA | c.1419G>T p.K473N (on ENST00000335670 / NM_134261.3; = p.K498N on NM_002943.3) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99832220; called by muse, mutect2, varscan2
- RPF1 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101039694; called by muse, mutect2, varscan2
- RPTN | c.1298A>G p.Q433R | Missense Mutation (SNP) | VAF 128/520 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100285287; called by muse, mutect2, varscan2
- RRAGA | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100998087; called by muse, mutect2, varscan2
- RREB1 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs558705748, COSV100619164; called by muse, mutect2, varscan2
- RSPH10B2 | c.1551_1553del p.F517del | In Frame Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs1207158312; called by pindel, varscan2
- RUFY2 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100700074, COSV100700082; called by muse, mutect2, varscan2
- RYR2 | c.7870C>T p.P2624S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.798); catalogued as rs1016563197, COSV63714989; called by muse, mutect2, varscan2
- SCLT1 | c.1620del p.A541Pfs*3 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as rs760494753; called by mutect2, varscan2
- SCRIB | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs967811731, COSV100252661; called by muse, mutect2, varscan2
- SDHAF3 | c.74del p.P25Rfs*11 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as COSV100836449; called by mutect2, pindel, varscan2
- SDK1 | c.5330G>A p.S1777N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV101268830; called by muse, mutect2, varscan2
- SEC24B | c.3076G>T p.A1026S | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99492979; called by muse, mutect2, varscan2
- SEC24C | c.1501C>A p.P501T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100226561; called by muse, mutect2, varscan2
- SETD6 | c.1202C>T p.T401M (on ENST00000219315 / NM_001160305.4; = p.T377M on NM_024860.3) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs777723120, COSV54699227; called by muse, mutect2, varscan2
- SH2D3C | c.976C>T p.R326C (on ENST00000314830 / NM_170600.3; = p.R169C on NM_005489.4) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs200833376, COSV100136477; called by muse, mutect2, varscan2
- SH3D19 | c.326_327insA p.G110Wfs*7 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | catalogued as COSV100455522; called by mutect2, pindel, varscan2
- SHOC1 | c.2027G>A p.S676N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs370722323; called by muse, mutect2, varscan2
- SI | c.4595G>T p.G1532V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014639, COSV52279492; called by muse, mutect2, varscan2
- SIPA1L2 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.351); catalogued as COSV99477306; called by muse, mutect2, varscan2
- SLA2 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV99481262; called by muse, mutect2
- SLC10A3 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99682019; called by muse, mutect2, varscan2
- SLC11A2 | c.605A>T p.N202I (on ENST00000394904 / NM_001379455.1; = p.N173I on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV100014498; called by muse, mutect2, varscan2
- SLC22A7 | c.1187C>T p.S396L (on ENST00000372585 / NM_153320.2; = p.S394L on NM_006672.3) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780208113, COSV51484001; called by muse, mutect2, varscan2
- SLC30A2 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100958494; called by muse, mutect2, varscan2
- SLC38A3 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs867256973, COSV101309870; called by muse, mutect2, varscan2
- SLC45A3 | c.841A>G p.S281G | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV100901081; called by muse, mutect2, varscan2
- SLC45A4 | c.1397G>A p.R466Q (on ENST00000517878 / NM_001286646.2; = p.R415Q on NM_001080431.2) | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.229); catalogued as rs769119550, COSV99196637; called by muse, mutect2, varscan2
- SLC9A5 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs375911278; called by muse, mutect2, varscan2
- SLC9A8 | c.957A>G p.S319= | Splice Region (SNP) | VAF 10/27 reads (37%) | catalogued as rs1236697402, COSV100846234; called by muse, mutect2, varscan2
- SLCO6A1 | c.1625del p.K542Rfs*13 | Frame Shift Del (DEL) | VAF 15/29 reads (52%) | catalogued as rs866444182; called by mutect2, pindel, varscan2
- SLITRK5 | c.1835G>A p.C612Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100280272, COSV100280380, COSV61525965; called by muse, mutect2, varscan2
- SMARCA1 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV100946378; called by muse, mutect2, varscan2
- SMARCC1 | c.2914C>T p.Q972* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99592368; called by muse, mutect2, varscan2
- SNX33 | c.1299del p.C435Afs*62 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs747082791; called by mutect2, pindel, varscan2
- SORBS3 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as COSV99530963; called by muse, mutect2, varscan2
- SORL1 | c.4417C>T p.R1473* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV99492992; called by muse, mutect2, varscan2
- SPAG6 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100509977; called by muse, mutect2, varscan2
- SPATA31E1 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100349994; called by muse, mutect2, varscan2
- SPEG | c.5902G>A p.A1968T | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV100403430; called by muse, mutect2, varscan2
- SPINT2 | c.278-2A>C p.X93_splice | Splice Site (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100007469; called by muse, mutect2, varscan2
- SPTA1 | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV100934415, COSV63756485; called by muse, mutect2, varscan2
- SPTBN4 | c.7670G>A p.R2557H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99398934; called by muse, mutect2, varscan2
- SRRM2 | c.7958A>G p.K2653R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV99241268; called by muse, mutect2, varscan2
- STK16 | c.912A>C p.Q304H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99850289; called by muse, mutect2, varscan2
- STMN3 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs556068883, COSV100899847; called by muse, mutect2, varscan2
- STS | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.226); catalogued as COSV54268443; called by muse, mutect2, varscan2
- SUCLG1 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV101205358; called by muse, mutect2
- SULF1 | c.223dup p.A75Gfs*48 | Frame Shift Ins (INS) | VAF 16/34 reads (47%) | catalogued as rs747316268; called by mutect2, varscan2
- SYNE2 | c.17141G>A p.R5714H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs200137127, COSV59952863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACC2 | c.3979C>T p.P1327S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100551664; called by muse, mutect2, varscan2
- TACC2 | c.8818G>A p.E2940K (on ENST00000334433; = p.E1018K on NM_006997.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53287902; called by muse, mutect2, varscan2
- TAOK1 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1249095811, COSV55601117; called by muse, mutect2, varscan2
- TBC1D25 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs1556985437, COSV65124715; called by muse, mutect2, varscan2
- TBL1XR1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.701); catalogued as rs1278353453, COSV70502086; called by muse, mutect2, varscan2
- TBX2 | c.411del p.F138Sfs*17 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as COSV99538794; called by mutect2, pindel, varscan2
- TDRD1 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99314147; called by muse, mutect2, varscan2
- TDRD7 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100795477; called by muse, mutect2, varscan2
- TEKT3 | c.1313T>G p.L438R | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100106824; called by muse, mutect2, varscan2
- TELO2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1567298664, COSV51977265; called by muse, mutect2, varscan2
- TFDP3 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV100033226; called by muse, mutect2, varscan2
- TG | c.7201G>A p.A2401T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as COSV99599333; called by muse, mutect2, varscan2
- THAP4 | c.1511-1G>T p.X504_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100398200; called by muse, mutect2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs746975641; called by mutect2, varscan2
- THRA | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV99225297; called by muse, mutect2, varscan2
- TIMM23 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); catalogued as rs1406647598; called by muse, mutect2, varscan2
- TLN1 | c.4634C>T p.A1545V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs943902713, COSV100147371; called by muse, mutect2, varscan2
- TMC1 | c.1717A>G p.I573V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV99918745; called by muse, mutect2, varscan2
- TMED9 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60264027; called by muse, mutect2, varscan2
- TMEFF2 | c.908del p.K303Rfs*19 | Frame Shift Del (DEL) | VAF 31/67 reads (46%) | catalogued as rs1553506636, COSV55829678; called by mutect2, pindel, varscan2
- TMEM102 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs759373786, COSV99548167; called by muse, mutect2, varscan2
- TMEM94 | c.657del p.F220Sfs*31 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs753764149; called by mutect2, pindel, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | catalogued as rs781830688; called by mutect2, varscan2
- TMLHE | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs199989202, COSV100544601; called by muse, mutect2, varscan2
- TMOD4 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99765900; called by muse, mutect2, varscan2
- TMPRSS5 | c.755G>T p.W252L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100244486; called by muse, mutect2, varscan2
- TMTC4 | c.2209C>G p.Q737E (on ENST00000376234 / NM_001350577.2; = p.Q756E on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV100168477; called by muse, mutect2, varscan2
- TMUB2 | c.865C>T p.R289* (on ENST00000538716 / NM_001353177.2; = p.R269* on NM_024107.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs540365819, COSV100116029; called by muse, mutect2, varscan2
- TNK2 | c.979G>A p.G327S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200104049, COSV100361052; called by muse, mutect2, varscan2
- TNNI1 | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100270158; called by muse, mutect2, varscan2
- TNRC6B | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100109130; called by muse, mutect2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TNS3 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100234867; called by muse, mutect2
- TRDN | c.1488del p.D497Mfs*49 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs1451530666; called by mutect2, pindel, varscan2
- TRIM67 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100792035; called by muse, mutect2, varscan2
- TSHZ1 | c.2698C>A p.L900M (on ENST00000580243 / NM_001308210.2; = p.L855M on NM_005786.6) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100433437, COSV100433580; called by muse, mutect2
- TSLP | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100789158; called by muse, mutect2, varscan2
- TTC17 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99234763; called by muse, mutect2, varscan2
- TTC38 | c.365+1G>A p.X122_splice | Splice Site (SNP) | VAF 17/48 reads (35%) | catalogued as COSV101123853; called by muse, mutect2, varscan2
- TTLL1 | c.1037A>G p.N346S | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV99840161; called by muse, mutect2, varscan2
- TTN | c.92801C>T p.T30934I (on ENST00000591111; = p.T23510I on NM_003319.4) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | PolyPhen probably damaging (0.998); catalogued as COSV100596720; called by muse, mutect2, varscan2
- TTN | c.85304C>T p.T28435M (on ENST00000591111; = p.T21011M on NM_003319.4) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | PolyPhen benign (0.001); catalogued as rs201998913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.46553C>A p.P15518H (on ENST00000591111; = p.P8094H on NM_003319.4) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | PolyPhen probably damaging (0.912); catalogued as COSV100596726, COSV59961406, COSV60175544; called by muse, mutect2, varscan2
- TTN | c.36277T>C p.F12093L (on ENST00000591111; = p.F4669L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | PolyPhen probably damaging (0.987); catalogued as COSV100596730; called by muse, mutect2, varscan2
- TXNDC11 | c.2837_2838del p.E946Gfs*7 (on ENST00000356957 / NM_001303447.2; = p.E919Gfs*7 on NM_015914.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs1567282879; called by pindel, varscan2
- UBQLN4 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as rs1392023564, COSV100849282; called by muse, mutect2, varscan2
- ULBP2 | c.539T>G p.M180R | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.158); catalogued as COSV100951201; called by muse, mutect2, varscan2
- USP6 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.305); catalogued as rs749836474, COSV100003179; called by muse, mutect2, varscan2
- USP9X | c.5070del p.F1690Lfs*8 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | catalogued as COSV100198262; called by mutect2, pindel, varscan2
- VARS1 | c.3476G>A p.S1159N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1208646159, COSV100791784; called by muse, mutect2
- VCAM1 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV99658231; called by muse, mutect2, varscan2
- VPS18 | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99592313; called by muse, mutect2, varscan2
- VPS8 | c.3937A>G p.N1313D (on ENST00000625842 / NM_001349294.1; = p.N1311D on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV99800902; called by muse, mutect2, varscan2
- WDR7 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs576060072, COSV99588694; called by muse, mutect2, varscan2
- WDR7 | c.1475T>C p.F492S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99588697; called by muse, mutect2, varscan2
- WDR7 | c.4468G>A p.V1490I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); catalogued as rs1398963885, COSV99588700; called by muse, mutect2, varscan2
- WDR90 | c.3038dup p.A1014Sfs*193 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | catalogued as rs752097396; called by mutect2, varscan2
- WDR91 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV60369632; called by muse, mutect2, varscan2
- WEE1 | c.1937A>G p.Y646C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100219605; called by muse, mutect2, varscan2
- WRN | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV99988373; called by muse, mutect2, varscan2
- WWC3 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.394); catalogued as COSV101081104, COSV66507785; called by muse, varscan2
- XAB2 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs4134822; called by muse, mutect2
- YEATS2 | c.3527C>T p.A1176V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100527517; called by muse, mutect2, varscan2
- ZFHX3 | c.314dup p.P106Afs*13 | Frame Shift Ins (INS) | VAF 35/89 reads (39%) | catalogued as rs769936196; called by mutect2, pindel, varscan2
- ZIC2 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV100891762, COSV66255273; called by muse, mutect2, varscan2
- ZNF106 | c.1722del p.S576Lfs*2 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as COSV55515697; called by mutect2, pindel, varscan2
- ZNF12 | c.1421_1423del p.F474del (on ENST00000405858 / NM_016265.4; = p.F436del on NM_006956.3) | In Frame Del (DEL) | VAF 24/55 reads (44%) | catalogued as rs1335286102; called by mutect2, pindel, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF131 | c.1343G>A p.R448H (on ENST00000509156 / NM_001330707.2; = p.R414H on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs758272060, COSV100185212; called by muse, mutect2, varscan2
- ZNF133 | c.518A>G p.Q173R (on ENST00000316358 / NM_001352454.2; = p.Q172R on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV100315299; called by muse, mutect2, varscan2
- ZNF398 | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100246818, COSV60066488; called by muse, mutect2
- ZNF468 | c.172T>A p.L58M | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV99700367; called by muse, mutect2, varscan2
- ZNF48 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as rs751944394, COSV100198034; called by muse, mutect2, varscan2
- ZNF488 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs782409705; called by muse, mutect2, varscan2
- ZNF584 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.355); catalogued as rs766375645, COSV100183204; called by muse, mutect2, varscan2
- ZNF598 | c.1535G>A p.S512N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.568); catalogued as COSV101461930; called by muse, mutect2, varscan2
- ZNF615 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as COSV100943719; called by muse, mutect2, varscan2
- ZNF628 | c.1705G>A p.G569S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV99219808; called by muse, mutect2, varscan2
- ZNF70 | c.979C>A p.R327S | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV100558832; called by muse, mutect2, varscan2
- ZNF721 | c.1999G>A p.G667R (on ENST00000338977; = p.G679R on NM_133474.4) | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100167075; called by muse, mutect2, varscan2
- ZNF746 | c.1805C>A p.P602Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as COSV100502376; called by muse, mutect2, varscan2
- ZNF780B | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55464458; called by muse, mutect2, varscan2
- ZNF835 | c.355T>C p.F119L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101606274; called by muse, mutect2, varscan2
- ADGRL2 | c.2279_2280del p.K760Rfs*9 (on ENST00000370717 / NM_001366005.1; = p.K747Rfs*9 on NM_012302.4) | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- ADNP | c.64del p.I22Yfs*14 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | called by pindel, varscan2
- APCDD1 | c.141del p.F47Lfs*38 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- ATP8A2 | c.3126dup p.G1043Wfs*43 | Frame Shift Ins (INS) | VAF 51/141 reads (36%) | called by mutect2, pindel, varscan2
- B3GLCT | c.238del p.S80Afs*3 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, varscan2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.196dup p.I66Nfs*19 | Frame Shift Ins (INS) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.5163del p.E1722Kfs*6 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- C1orf94 | c.1341dup p.P448Sfs*162 (on ENST00000488417 / NM_001134734.2; = p.P258Sfs*162 on NM_032884.5) | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- CCDC178 | c.1422dup p.S475Ifs*6 | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- CD93 | c.943del p.A315Pfs*273 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- CEP170 | c.611del p.N204Tfs*11 | Frame Shift Del (DEL) | VAF 46/219 reads (21%) | called by mutect2, pindel, varscan2
- CHRM4 | c.1249_1251del p.N417del | In Frame Del (DEL) | VAF 15/34 reads (44%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.1430dup p.P478Sfs*4 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- CRIM1 | c.261del p.L88Cfs*48 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | called by mutect2, pindel, varscan2
- CRISP1 | c.26dup p.L9Ffs*19 | Frame Shift Ins (INS) | VAF 19/35 reads (54%) | called by mutect2, pindel, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 47/120 reads (39%) | called by mutect2, pindel, varscan2
- DICER1 | c.4049del p.K1350Rfs*29 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- DNHD1 | c.1253_1254del p.H418Lfs*14 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by pindel, varscan2
- DVL3 | c.775_776del p.F259Lfs*14 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | called by mutect2, pindel, varscan2
- EDN3 | c.262del p.A88Pfs*121 (on ENST00000337938 / NM_001302455.2; = p.A88Pfs*110 on NM_207032.3) | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- FAM124A | c.634dup p.S212Ffs*17 (on ENST00000322475 / NM_001242312.2; = p.S248Ffs*17 on NM_145019.4) | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- FAM133A | c.623del p.K208Rfs*15 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- FCGBP | c.8870T>C p.V2957A | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FITM1 | c.421dup p.A141Gfs*27 | Frame Shift Ins (INS) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- FYB2 | c.1851del p.E618Rfs*24 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, varscan2
- GPR82 | c.142del p.T48Hfs*11 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- HNRNPU | c.343del p.A115Rfs*82 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- HPDL | c.851del p.P284Lfs*31 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- IDUA | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- IGHM | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.398); called by muse, mutect2
- IGKV1-9 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- IQSEC2 | c.1777del p.L593Cfs*14 (on ENST00000642864 / NM_001111125.3; = p.L388Cfs*14 on NM_015075.2) | Frame Shift Del (DEL) | VAF 9/15 reads (60%) | called by mutect2, varscan2
- KDM7A | c.289del p.R97Gfs*41 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- L2HGDH | c.521del p.K174Rfs*9 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- MAP2 | c.4420del p.T1474Qfs*14 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- MIA3 | c.503del p.N168Tfs*15 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | called by mutect2, pindel, varscan2
- MSTN | c.960del p.K320Nfs*40 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- NAA16 | c.1938del p.K646Nfs*2 | Frame Shift Del (DEL) | VAF 46/135 reads (34%) | called by mutect2, pindel, varscan2
- NBPF11 | c.883T>A p.L295M | Missense Mutation (SNP) | VAF 147/574 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NEB | c.1811dup p.N604Kfs*12 | Frame Shift Ins (INS) | VAF 11/50 reads (22%) | called by mutect2, varscan2
- NPY1R | c.1150dup p.I384Nfs*12 | Frame Shift Ins (INS) | VAF 32/119 reads (27%) | called by mutect2, pindel, varscan2
- NUTM2F | c.1175dup p.E393* | Frame Shift Ins (INS) | VAF 22/206 reads (11%) | called by mutect2, varscan2
- OPLAH | c.3816del p.E1274Sfs*24 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- PCF11 | c.2399del p.G800Efs*5 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- PCSK5 | c.329dup p.R111Afs*7 | Frame Shift Ins (INS) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- PCSK5 | c.2027del p.P676Lfs*38 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- PDE11A | c.2405dup p.N802Kfs*4 | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | called by pindel, varscan2
- PEX3 | c.449del p.N150Mfs*27 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- PTCH1 | c.3606del p.S1203Afs*52 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- RAB11FIP4 | c.232del p.V78Cfs*4 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- RAI1 | c.4051del p.A1351Pfs*7 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- RBM43 | c.729del p.K243Nfs*5 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by mutect2, pindel, varscan2
- REXO1 | c.995del p.G332Afs*161 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- RHOBTB2 | c.2059_2061del p.K687del | In Frame Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- RIF1 | c.4514del p.K1505Rfs*18 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- RSPH10B | c.1551_1553del p.F517del | In Frame Del (DEL) | VAF 17/107 reads (16%) | called by pindel, varscan2
- SACS | c.13265del p.P4422Lfs*30 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- SCAF1 | c.3539_3540del p.P1180Hfs*10 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- SERPINE2 | c.824dup p.T276Dfs*40 | Frame Shift Ins (INS) | VAF 7/83 reads (8%) | called by mutect2, pindel
- SHROOM2 | c.3005dup p.E1003Rfs*18 | Frame Shift Ins (INS) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- SSX2IP | c.842_844del p.L281del | In Frame Del (DEL) | VAF 5/32 reads (16%) | called by pindel, varscan2
- ST6GAL2 | c.1100dup p.L367Ffs*14 | Frame Shift Ins (INS) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- TARS3 | c.1636dup p.C546Lfs*7 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- TAS2R3 | c.22del p.V8Cfs*3 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- TBC1D19 | c.53del p.K18Sfs*29 | Frame Shift Del (DEL) | VAF 55/150 reads (37%) | called by mutect2, pindel, varscan2
- TGFB3 | c.491_502del p.N164_R167del | In Frame Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- TMEM63C | c.35del p.G12Efs*6 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- TRAPPC5 | c.429_434del p.A144_G145del | In Frame Del (DEL) | VAF 13/23 reads (57%) | called by mutect2, pindel, varscan2
- TTK | c.575del p.K192Sfs*18 | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- USP9X | c.82del p.L28Sfs*51 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- VMAC | c.420del p.G141Vfs*80 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- VWA3B | c.552dup p.E185Rfs*25 | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- ZBTB2 | c.652del p.E218Rfs*19 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- ZNF112 | c.1222del p.I408Sfs*11 (on ENST00000337401 / NM_001083335.2; = p.I402Sfs*11 on NM_013380.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- ZNF292 | c.3414dup p.G1139Rfs*5 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- ABCG1 | c.1782G>A p.Q594= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100493887; called by muse, mutect2, varscan2
- ABHD17B | c.165C>T p.D55= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV100330092; called by muse, varscan2
- ADAMTS10 | c.1116C>T p.R372= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs545679370, COSV54352996; called by muse, mutect2, varscan2
- ADAMTS17 | c.633G>A p.T211= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as rs375365760; called by muse, mutect2, varscan2
- ADAMTS8 | c.2037C>T p.C679= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs778082121, COSV57290891; called by muse, mutect2, varscan2
- ADGRA1 | c.144C>T p.T48= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs755671458, COSV101658572, COSV101658585; called by muse, mutect2, varscan2
- AGXT2 | c.945C>T p.G315= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs761904321, COSV99183711; called by muse, mutect2, varscan2
- AP3B2 | c.447T>C p.A149= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV99916103; called by muse, mutect2, varscan2
- ARFGEF2 | c.3615C>T p.R1205= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100904027; called by muse, mutect2, varscan2
- ARHGAP44 | c.153C>T p.T51= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs192254681; called by muse, mutect2, varscan2
- ARMC6 | c.633G>A p.Q211= (on ENST00000392336; = p.Q186= on NM_033415.4) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99522940; called by muse, mutect2, varscan2
- ATRNL1 | c.3105C>A p.T1035= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100369490; called by muse, mutect2, varscan2
- BAZ2A | c.3525A>G p.L1175= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99464849; called by muse, mutect2, varscan2
- BDKRB2 | c.321C>T p.A107= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100020918; called by muse, mutect2
- BHLHE40 | c.927C>T p.S309= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99847958; called by muse, mutect2, varscan2
- BOC | c.1989G>A p.R663= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99848205; called by muse, mutect2
- BRF1 | c.1893C>T p.S631= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs770337786, COSV100526880; called by muse, mutect2, varscan2
- BRSK1 | c.996C>T p.R332= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs139469654; called by muse, mutect2, varscan2
- CACNA2D2 | c.960G>A p.T320= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1334771827, COSV99816975; called by muse, mutect2, varscan2
- CDC40 | c.879A>C p.A293= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100309155, COSV57009145; called by muse, mutect2, varscan2
- COA6 | c.174C>T p.C58= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV100784540, COSV64016890; called by muse, mutect2
- CRISPLD1 | c.933C>T p.Y311= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs753246288, COSV100081629; called by muse, mutect2, varscan2
- CSK | c.618C>T p.F206= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs571010572, COSV54975660; called by muse, mutect2, varscan2
- DAPK1 | c.2982C>T p.D994= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1000898070, COSV100801149; called by muse, mutect2, varscan2
- DCAF6 | c.1128T>C p.S376= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV100393984; called by muse, mutect2, varscan2
- DDX24 | c.1002C>T p.D334= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100427829; called by muse, mutect2, varscan2
- DDX24 | c.486G>A p.G162= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100427830; called by muse, mutect2, varscan2
- DMXL2 | c.4539A>G p.V1513= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99195998; called by muse, mutect2, varscan2
- DNAJB12 | c.273C>T p.A91= (on ENST00000338820; = p.A57= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs764189866, COSV100123658; called by muse, mutect2, varscan2
- DOK5 | c.762C>T p.A254= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs757709862, COSV99373320; called by muse, mutect2, varscan2
- DPP3 | c.1143C>T p.F381= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs371574227; called by muse, mutect2, varscan2
- DRD5 | c.162C>A p.T54= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100431563; called by muse, mutect2, varscan2
- DRG2 | c.838C>T p.L280= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV99231357; called by muse, mutect2, varscan2
- DSCAM | c.5283A>G p.A1761= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV68025656; called by muse, mutect2, varscan2
- ECI2 | c.945A>G p.G315= (on ENST00000380118 / NM_206836.3; = p.G285= on NM_006117.2) | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100326334; called by muse, mutect2
- EFHC2 | c.717A>G p.S239= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV101375443; called by muse, mutect2, varscan2
- EPHB1 | c.1488G>A p.L496= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV101212740; called by muse, mutect2, varscan2
- ERC1 | c.1800G>A p.R600= (on ENST00000360905 / NM_178040.4; = p.R572= on NM_178039.4) | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1444532246, COSV100705659; called by muse, mutect2
- FARSA | c.1365T>A p.I455= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99535751; called by muse, mutect2, varscan2
- FGGY | c.825G>A p.G275= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100363893; called by muse, mutect2
- FREM1 | c.4065C>T p.H1355= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV101083895; called by muse, mutect2, varscan2
- GBF1 | c.4737A>G p.Q1579= (on ENST00000369983 / NM_001377137.1; = p.Q1578= on NM_004193.3) | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV100890339; called by muse, mutect2, varscan2
- GJB7 | c.288C>A p.A96= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs200785675, COSV99738072; called by muse, mutect2, varscan2
- H4C8 | c.60C>T p.R20= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs376550213; called by muse, mutect2, varscan2
- HIP1 | c.672G>A p.P224= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs782093444, COSV100417013; called by muse, mutect2, varscan2
- HIPK4 | c.601C>T p.L201= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52526568; called by muse, mutect2, varscan2
- HIVEP3 | c.1137G>A p.A379= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1033430459, COSV56024520; called by muse, mutect2, varscan2
- HLA-DPA1 | c.723C>A p.T241= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV101343095, COSV70088653; called by muse, mutect2
- IFI16 | c.834T>G p.T278= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99857095; called by muse, mutect2, varscan2
- IFI16 | c.2301G>A p.K767= (on ENST00000295809 / NM_001364867.2; = p.K711= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV55542185; called by muse, mutect2, varscan2
- INPPL1 | c.2592C>T p.G864= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99995914; called by muse, mutect2, varscan2
- IQCB1 | c.1113C>T p.L371= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs1257528843, COSV100181576; called by muse, mutect2, varscan2
- ITGB3 | c.1713G>A p.G571= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV101457549; called by muse, mutect2, varscan2
- ITGB7 | c.906C>T p.G302= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99913934; called by muse, mutect2, varscan2
- KCNK16 | c.123T>G p.A41= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100949089; called by muse, mutect2, varscan2
- KIF21B | c.4374C>T p.C1458= (on ENST00000422435 / NM_001252100.2; = p.C1445= on NM_017596.4) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100143829; called by muse, mutect2, varscan2
- KLHL25 | c.1512A>G p.T504= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as COSV100563459; called by muse, mutect2, varscan2
- KMO | c.870C>T p.C290= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV100844669; called by muse, mutect2, varscan2
- KMT2A | c.1695G>A p.L565= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100628100; called by muse, mutect2, varscan2
- KPNA3 | c.153T>C p.V51= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99903932; called by muse, mutect2
- LAMP1 | c.627G>A p.S209= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs530779384, COSV60211225; called by muse, mutect2, varscan2
- LRP2 | c.4368C>T p.H1456= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99786764; called by muse, mutect2, varscan2
- LRRK2 | c.3132T>C p.S1044= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100109380; called by muse, mutect2, varscan2
- LRRN3 | c.2010C>A p.T670= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100068265; called by muse, mutect2, varscan2
- MARCHF4 | c.786C>A p.P262= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99814099; called by muse, mutect2, varscan2
- MFAP4 | c.282C>T p.R94= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs777556848, COSV100218785; called by muse, mutect2, varscan2
- MMEL1 | c.2217C>T p.D739= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs749252835, COSV56518451; called by muse, mutect2, varscan2
- MN1 | c.3738G>A p.A1246= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs767225766, COSV56558267; called by muse, mutect2, varscan2
- MROH2B | c.4626A>G p.L1542= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV101270529; called by muse, mutect2, varscan2
- MTUS2 | c.2313A>T p.G771= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV101462093; called by muse, mutect2, varscan2
- MYH1 | c.1137T>C p.D379= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs750080340, COSV99875021; called by muse, mutect2, varscan2
- NAT10 | c.1647C>T p.S549= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs577046723, COSV57663760, COSV57666589; called by muse, mutect2
- NAV2 | c.5091G>A p.R1697= (on ENST00000396087 / NM_001244963.2; = p.R1641= on NM_145117.5) | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs764873468, COSV100216251; called by muse, mutect2, varscan2
- NCKIPSD | c.1410G>A p.L470= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99583747; called by muse, mutect2, varscan2
- NCOA7 | c.2271C>T p.R757= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs764058240, COSV99996567; called by muse, mutect2, varscan2
- NCOR1 | c.6219C>T p.P2073= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV99247857; called by muse, mutect2, varscan2
- NUFIP2 | c.1968T>C p.F656= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99837247; called by muse, mutect2, varscan2
- OBSCN | c.2523T>C p.G841= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as COSV99473664; called by muse, mutect2, varscan2
- OLFML2B | c.1740C>A p.A580= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99668081; called by muse, mutect2, varscan2
- OPN3 | c.1197T>C p.V399= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV100087084; called by muse, mutect2, varscan2
- OR10A7 | c.513A>G p.P171= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV100406508; called by muse, mutect2
- OR10K1 | c.151C>T p.L51= | Silent (SNP) | VAF 38/184 reads (21%) | catalogued as rs1557872548, COSV99193257; called by muse, mutect2, varscan2
- OR5H6 | c.504C>T p.G168= (on ENST00000642105; = p.G152= on NM_001005479.2) | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs748894936, COSV101051744; called by muse, mutect2, varscan2
- OR6C4 | c.549G>T p.V183= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV101263128, COSV101263130; called by muse, mutect2, varscan2
- PARP9 | c.1737A>G p.P579= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100830962; called by muse, mutect2, varscan2
- PBXIP1 | c.1464G>A p.E488= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100870017; called by muse, mutect2, varscan2
- PCDH19 | c.687C>T p.T229= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs1380357181, COSV99718897; called by muse, mutect2, varscan2
- PCDHA13 | c.1245C>T p.R415= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV99165115; called by muse, mutect2, varscan2
- PCDHA6 | c.1836G>A p.Q612= | Silent (SNP) | VAF 63/113 reads (56%) | catalogued as COSV65345796; called by muse, mutect2, varscan2
- PCDHGA4 | c.1965C>T p.G655= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs745612694, COSV53952266, COSV99531950; called by muse, mutect2, varscan2
- PCNX2 | c.3165A>G p.P1055= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99266256; called by muse, mutect2, varscan2
- PGLYRP2 | c.1236C>A p.T412= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV99483793; called by muse, mutect2, varscan2
- PHC3 | c.2046C>T p.H682= (on ENST00000494943 / NM_001308116.2; = p.H694= on NM_024947.4) | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as rs1437846501, COSV101520142; called by muse, mutect2, varscan2
- PIKFYVE | c.348C>A p.T116= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100009946; called by muse, mutect2, varscan2
- PLCG2 | c.3150G>A p.P1050= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs376070393; called by muse, mutect2, varscan2
- PML | c.2355G>A p.V785= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99166714; called by muse, mutect2, varscan2
- PPP1R10 | c.2007T>C p.P669= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100919756; called by muse, mutect2, varscan2
- PRRC2B | c.5544C>A p.P1848= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs761349319, COSV100260873; called by mutect2, varscan2
- PRRT3 | c.942C>T p.D314= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs370676875; called by muse, mutect2, varscan2
- PRXL2A | c.555C>T p.F185= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as rs150904688; called by muse, mutect2, varscan2
- PSMC5 | c.771G>A p.S257= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs758535750, COSV99856243; called by muse, varscan2
- PTPRK | c.2175C>T p.C725= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs750995140, COSV100950316; called by muse, mutect2, varscan2
- RCN2 | c.942T>C p.H314= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1470659640, COSV100312713; called by muse, mutect2, varscan2
- REPIN1 | c.1470C>T p.P490= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs757466977, COSV101262585; called by muse, mutect2, varscan2
- RHOBTB2 | c.1521T>C p.D507= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99310737; called by muse, mutect2, varscan2
- RIMS1 | c.2760A>G p.V920= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV99324510; called by muse, mutect2, varscan2
- RLF | c.3246A>G p.S1082= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV65652339; called by muse, mutect2, varscan2
- RTTN | c.6087G>A p.Q2029= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99731232; called by muse, mutect2, varscan2
- RUFY4 | c.1626C>T p.G542= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs778171785, COSV100722951; called by muse, mutect2, varscan2
- SAMD9 | c.2373C>T p.Y791= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs189020649, COSV66076095; called by muse, mutect2, varscan2
- SCN10A | c.3144A>G p.P1048= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV101479263; called by muse, mutect2, varscan2
- SDK2 | c.3015C>T p.G1005= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs775438348, COSV101166947, COSV66184768; called by muse, varscan2
- SECTM1 | c.553C>T p.L185= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99486130; called by muse, mutect2, varscan2
- SEMA4C | c.447T>C p.H149= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100560756; called by muse, mutect2, varscan2
- SEPTIN6 | c.1209T>A p.A403= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV100595418; called by muse, mutect2, varscan2
- SLAMF1 | c.159T>C p.N53= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99348982; called by muse, mutect2, varscan2
- SLC17A3 | c.667T>C p.L223= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV100399087; called by muse, varscan2
- SLC27A3 | c.1479G>A p.Q493= (on ENST00000271857; = p.Q365= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV99669727; called by muse, mutect2
- SLC41A1 | c.1407C>G p.G469= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV100900333; called by muse, mutect2
- SLC6A16 | c.1536C>T p.S512= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs776801542, COSV100242583; called by mutect2, varscan2
- SPHK2 | c.984C>T p.R328= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99709184; called by muse, mutect2, varscan2
- SPPL2B | c.282G>A p.A94= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs368921628; called by muse, mutect2, varscan2
- SVIL | c.2397C>T p.G799= (on ENST00000355867 / NM_021738.3; = p.G373= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs770586568, COSV100880968; called by muse, mutect2, varscan2
- SVOPL | c.501G>A p.T167= (on ENST00000419765; = p.T15= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs371993600; called by muse, mutect2, varscan2
- SYNPO2L | c.1830C>T p.R610= (on ENST00000394810 / NM_001114133.3; = p.R386= on NM_024875.5) | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as COSV65737414; called by muse, mutect2, varscan2
- TEKT3 | c.679C>T p.L227= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs748211346, COSV100106826; called by muse, mutect2, varscan2
- TGFB2 | c.1140C>T p.C380= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs201129153; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TMEM120A | c.303G>A p.L101= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99951258; called by muse, mutect2, varscan2
- TNIP1 | c.768C>T p.N256= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100161142; called by muse, mutect2, varscan2
- TPST2 | c.247T>C p.L83= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs1569181605, COSV100113979; called by muse, mutect2, varscan2
- TRAPPC8 | c.1725G>A p.G575= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99350631; called by muse, mutect2, varscan2
- TRIM11 | c.1368G>A p.R456= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs149103830; called by muse, mutect2, varscan2
- TRIM62 | c.771A>G p.G257= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV52220571, COSV99357665; called by muse, mutect2, varscan2
- TRPM3 | c.3450A>C p.P1150= (on ENST00000357533 / NM_001366142.2; = p.P1005= on NM_020952.6) | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100676725, COSV62591903; called by muse, mutect2, varscan2
- TRRAP | c.4809G>A p.V1603= (on ENST00000359863 / NM_001244580.1; = p.V1585= on NM_003496.3) | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1463770988, COSV100722065; called by muse, mutect2, varscan2
- TULP4 | c.3369G>A p.Q1123= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100893180; called by muse, mutect2, varscan2
- USP44 | c.555A>G p.V185= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99311617; called by muse, mutect2, varscan2
- USP47 | c.513C>T p.S171= (on ENST00000399455 / NM_001372095.1; = p.S83= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100359225; called by muse, mutect2, varscan2
- VPREB3 | c.312C>A p.P104= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99963460; called by muse, mutect2, varscan2
- VPS13A | c.7482T>C p.G2494= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100652243, COSV62429248; called by muse, varscan2
- WDCP | c.87C>T p.T29= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs146251104; called by muse, mutect2, varscan2
- WDR24 | c.1566C>T p.L522= (on ENST00000248142; = p.L392= on NM_032259.4) | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs372112340; called by muse, mutect2, varscan2
- WDR6 | c.2460G>A p.P820= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs539982627, COSV58247110; called by muse, mutect2, varscan2
- ZIC1 | c.471C>T p.N157= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV51552922, COSV99292466; called by muse, mutect2
- ZNF385D | c.1104T>C p.T368= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99873562; called by muse, mutect2, varscan2
- ZNF462 | c.5901C>T p.G1967= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs1391458930, COSV52936391; called by muse, mutect2, varscan2
- ZNF766 | c.519G>A p.L173= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100765265; called by muse, mutect2, varscan2
- ACP4 | chr19:50798305 G>T | 3'Flank (SNP) | VAF 24/49 reads (49%) | catalogued as COSV99567570; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825228 A>T | 5'Flank (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- AL590867.2 | n.22A>G | RNA (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2
- ANAPC11 | c.110-422del | Intron (DEL) | VAF 7/11 reads (64%) | called by mutect2, varscan2
- AP001042.1 | n.2593T>C | RNA (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179565C>T | Intron (SNP) | VAF 17/29 reads (59%) | catalogued as COSV99859417; called by muse, mutect2, varscan2
- DNM1P46 | n.930C>T | RNA (SNP) | VAF 10/44 reads (23%) | catalogued as rs201407168; called by muse, varscan2
- FAM71F1 | c.*1G>A | 3'UTR (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100170852; called by muse, mutect2, varscan2
- GNAO1 | c.723+4065A>C | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as rs1455791075, COSV99340743; called by muse, varscan2
- HADH | c.710-812C>T | Intron (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100531195; called by muse, mutect2, varscan2
- MFSD4B | c.*186del | 3'UTR (DEL) | VAF 25/48 reads (52%) | catalogued as rs540972233; called by mutect2, varscan2
- NCKAP5L | c.192+29del | Intron (DEL) | VAF 4/42 reads (10%) | catalogued as rs752038145; called by pindel, varscan2
- PCDHGA9 | c.2424+17dup | Intron (INS) | VAF 14/36 reads (39%) | catalogued as rs759226115; called by mutect2, varscan2
- PKD1L2 | n.929G>A | RNA (SNP) | VAF 7/26 reads (27%) | catalogued as rs772471006; called by muse, mutect2, varscan2
- RPS6KA1 | c.*238del | 3'UTR (DEL) | VAF 10/22 reads (45%) | catalogued as rs751407416; called by mutect2, varscan2
- SLC3A2 | chr11:62855021 T>C | 5'Flank (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- SREK1 | chr5:66144532 C>A | 5'Flank (SNP) | VAF 34/74 reads (46%) | catalogued as rs772307778, COSV100485596; called by muse, mutect2, varscan2
- STRADA | c.1100+18G>T | Intron (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99368454; called by muse, mutect2, varscan2
- ZNF648 | c.*2G>T | 3'UTR (SNP) | VAF 24/121 reads (20%) | catalogued as COSV100374451; called by muse, mutect2, varscan2
